MMRF case MMRF_1431 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/44d76370-2d6f-4faf-a5f8-af9d4a185394

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 75 years; Vital status: Dead; Days to death: 1,245 days (3.4 years).

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 75.3 years (27,515 days); ISS stage: II; Days to last known disease status: 1,245 days (3.4 years); Days to last follow up: 1,245 days (3.4 years).
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 1,230 days (3.4 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 33 days; Days to treatment end: 837 days (2.3 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 1,245.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -9 (ECOG 0): M Protein 3.36 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.43 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 15.8 mg/dL; Immunoglobulin G 49 g/L; Immunoglobulin A 0.15 g/L; Immunoglobulin M 0.05 g/L; Beta 2 Microglobulin 3.21 µg/mL; Lactate Dehydrogenase 2.28 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 3.62 ×10⁹/L; Platelets 169 ×10⁹/L; Creatinine 76 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.25 mmol/L; Albumin 33 g/L; Total Protein 8.8 g/dL; Glucose 8.91 mmol/L.
- Day 84 (ECOG 0): M Protein 1.43 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.83 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 5.19 mg/dL; Immunoglobulin G 17.5 g/L; Immunoglobulin A 0.43 g/L; Immunoglobulin M 0.21 g/L; Beta 2 Microglobulin 0.49 µg/mL; Hemoglobin 7.63 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 1.94 ×10⁹/L; Platelets 178 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.13 mmol/L; Albumin 34 g/L; Total Protein 6.5 g/dL; Glucose 9.85 mmol/L.
- Day 168 (ECOG 0): M Protein 0.36 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.18 mg/dL; Immunoglobulin G 6.98 g/L; Immunoglobulin A 0.5 g/L; Immunoglobulin M 0.21 g/L; Lactate Dehydrogenase 3.65 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 4.13 ×10⁹/L; Platelets 115 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.23 mmol/L; Albumin 40 g/L; Total Protein 6 g/dL; Glucose 4.57 mmol/L.
- Day 266 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 0.87 mg/dL; Lactate Dehydrogenase 3.08 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 3.4 ×10⁹/L; Platelets 167 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.38 mmol/L; Albumin 39 g/L; Total Protein 5.6 g/dL; Glucose 7.15 mmol/L.
- Day 357 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 0.61 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.77 mg/dL; Immunoglobulin G 5.73 g/L; Immunoglobulin A 0.53 g/L; Immunoglobulin M 0.21 g/L; Lactate Dehydrogenase 3.27 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.52 ×10⁹/L; Platelets 177 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.3 mmol/L; Albumin 37.4 g/L; Total Protein 5.7 g/dL; Glucose 5.45 mmol/L.
- Day 441: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.02 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.77 mg/dL; Immunoglobulin G 4.86 g/L; Immunoglobulin A 0.51 g/L; Immunoglobulin M 0.21 g/L; Hemoglobin 6.45 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 1.92 ×10⁹/L; Platelets 138 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.2 mmol/L; Albumin 36 g/L; Total Protein 5.2 g/dL; Glucose 8.47 mmol/L.
- Day 537: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.98 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.24 mg/dL; Immunoglobulin G 5.67 g/L; Immunoglobulin A 0.78 g/L; Immunoglobulin M 0.24 g/L; Hemoglobin 6.76 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 97 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.2 mmol/L; Albumin 35 g/L; Total Protein 6.1 g/dL; Glucose 8.42 mmol/L.
- Day 595: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.46 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.25 mg/dL; Immunoglobulin G 5.86 g/L; Immunoglobulin A 0.96 g/L; Immunoglobulin M 0.28 g/L; Hemoglobin 6.39 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 106 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.35 mmol/L; Albumin 36 g/L; Total Protein 6.2 g/dL; Glucose 7.65 mmol/L.
- Day 705 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 1.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.13 mg/dL; Immunoglobulin G 6.56 g/L; Immunoglobulin A 1.19 g/L; Immunoglobulin M 0.21 g/L; Hemoglobin 6.51 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 164 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.18 mmol/L; Albumin 35.8 g/L; Total Protein 5.8 g/dL; Glucose 10.1 mmol/L.
- Day 788 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 2.51 mg/dL; Immunoglobulin G 6.44 g/L; Immunoglobulin A 1.31 g/L; Immunoglobulin M 0.28 g/L; Hemoglobin 6.57 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 2.67 ×10⁹/L; Creatinine 99.9 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.35 mmol/L; Albumin 39 g/L; Total Protein 5.9 g/dL; Glucose 10.6 mmol/L.
- Day 901 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 2.44 mg/dL; Immunoglobulin G 6.66 g/L; Immunoglobulin A 1.59 g/L; Immunoglobulin M 0.39 g/L; Hemoglobin 6.32 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 2.72 ×10⁹/L; Platelets 126 ×10⁹/L; Creatinine 105 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.28 mmol/L; Albumin 38 g/L; Total Protein 6.2 g/dL; Glucose 8.31 mmol/L.
- Day 959: Serum Free Immunoglobulin Light Chain, Kappa 1.92 mg/dL; Immunoglobulin G 5.84 g/L; Immunoglobulin A 1.43 g/L; Immunoglobulin M 0.18 g/L; Hemoglobin 6.76 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 1.83 ×10⁹/L; Platelets 145 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.2 mmol/L; Albumin 38 g/L; Total Protein 5.9 g/dL; Glucose 11.4 mmol/L.
- Day 1,069: Serum Free Immunoglobulin Light Chain, Kappa 2.73 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.95 mg/dL; Immunoglobulin G 6.19 g/L; Immunoglobulin A 1.73 g/L; Immunoglobulin M 0.3 g/L; Hemoglobin 6.32 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 1.72 ×10⁹/L; Platelets 134 ×10⁹/L; Creatinine 77.8 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.3 mmol/L; Albumin 35 g/L; Total Protein 5.6 g/dL; Glucose 15.7 mmol/L.
- Day 1,153: Immunoglobulin G 5.65 g/L; Immunoglobulin A 2.09 g/L; Immunoglobulin M 0.29 g/L; Lactate Dehydrogenase 2.92 µkat/L; Hemoglobin 6.08 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 2.05 ×10⁹/L; Platelets 145 ×10⁹/L; Creatinine 72.5 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.2 mmol/L; Albumin 33 g/L; Total Protein 6 g/dL; Glucose 20.6 mmol/L.

Other clinical attributes
- Day -9: Weight: 85 kg; Height: 182 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Breast Cancer.

Biospecimens (2 samples)
- Sample MMRF_1431_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -9 days.
- Sample MMRF_1431_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -9 days.
